Somatic mutation profile of tumor specimen ALCH-B3FV-TTP1-A (aliquot ALCH-B3FV-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3FV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.9 years (26,256 days).
Specimen ALCH-B3FV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd3443a2-7823-461b-a710-fab9c6f84339.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3FV-NB1-A (Blood Derived Normal), aliquot ALCH-B3FV-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d34ec0f-caaf-49d9-9570-3b680ba99d82

The open-access MAF lists 658 somatic variants for this specimen: 456 protein-altering or splice-affecting, 126 silent, 76 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 386, Silent 126, Nonsense Mutation 40, Intron 40, 3'UTR 14, RNA 11, Splice Site 8, Splice Region 7, Frame Shift Del 6, 5'Flank 5, Frame Shift Ins 4, Nonstop Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 45/311 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AC099489.1 | c.3587C>T p.A1196V | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1007560752; called by muse, mutect2
- ADAM17 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV60397370; called by muse, mutect2
- ADGRV1 | c.7039G>A p.D2347N | Missense Mutation (SNP) | VAF 13/257 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67989816; called by muse, mutect2
- AKR1B10 | c.426G>T p.W142C | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV100610238; called by muse, mutect2, varscan2
- ANO4 | c.2546C>T p.S849L (on ENST00000392977 / NM_001286615.2; = p.S814L on NM_178826.4) | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs376008571, COSV54610752; called by muse, mutect2
- ARFGEF3 | c.5288C>T p.S1763F | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867571171, COSV99295007; called by muse, mutect2
- ARID1A | c.4609C>T p.Q1537* | Nonsense Mutation (SNP) | VAF 5/44 reads (11%) | catalogued as COSV61372580; called by muse, mutect2
- ARMC3 | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 26/261 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV53057249; called by muse, mutect2
- ATF7IP | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 48/288 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.011); catalogued as COSV53765923; called by muse, mutect2, varscan2
- ATG9B | c.2316C>G p.F772L | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52488396; called by muse, mutect2, varscan2
- ATOX1 | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); catalogued as rs981894812; called by muse, mutect2
- ATRX | c.3121G>A p.D1041N | Missense Mutation (SNP) | VAF 17/197 reads (9%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.031); catalogued as rs1386901513; called by muse, mutect2
- ATRX | c.753G>T p.K251N | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64881288; called by muse, mutect2
- B4GALT6 | c.55A>G p.I19V | Missense Mutation (SNP) | VAF 43/384 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs773183141; called by muse, mutect2, varscan2
- BEND3 | c.1724C>T p.S575L | Missense Mutation (SNP) | VAF 19/271 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs782415484, COSV64681394; called by muse, mutect2
- BICD1 | c.2119G>T p.A707S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.998); catalogued as rs868324185; called by muse, mutect2, varscan2
- BOC | c.1918C>T p.R640C | Missense Mutation (SNP) | VAF 34/470 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767756953, COSV56352222; called by muse, mutect2
- BTF3 | c.302C>G p.S101C (on ENST00000380591 / NM_001037637.1; = p.S57C on NM_001207.4) | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.935); catalogued as rs1215511257, COSV100246671; called by muse, mutect2
- CAMTA1 | c.447C>A p.Y149* | Nonsense Mutation (SNP) | VAF 28/340 reads (8%) | catalogued as COSV100351871, COSV57928378; called by muse, mutect2
- CAND2 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 23/176 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as rs757871348, COSV99928675; called by muse, mutect2, varscan2
- CCDC113 | c.760C>G p.L254V | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); catalogued as COSV99541077; called by muse, mutect2
- CCDC22 | c.1258C>T p.Q420* | Nonsense Mutation (SNP) | VAF 16/360 reads (4%) | catalogued as COSV100873255; called by muse, mutect2
- CDH17 | c.2007G>T p.K669N | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as COSV50340847; called by muse, mutect2
- CDH23 | c.4465G>C p.E1489Q | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV56490181; called by muse, mutect2, varscan2
- CDIN1 | c.845G>C p.*282Sext*2 (on ENST00000437989; = p.*184Sext*2 on NM_032499.6 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 14/152 reads (9%) | catalogued as rs1484507860; called by muse, mutect2
- CFAP47 | c.9283G>C p.G3095R | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV66220706; called by muse, mutect2, varscan2
- CILP2 | c.1783G>T p.D595Y | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs147931006, COSV52274817; called by muse, mutect2, varscan2
- COL11A1 | c.4537G>T p.G1513C | Missense Mutation (SNP) | VAF 19/474 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62184768, COSV62187287; called by muse, mutect2
- COL2A1 | c.1421G>A p.G474D | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61532811; called by muse, mutect2
- CPA3 | c.808G>C p.D270H | Missense Mutation (SNP) | VAF 12/215 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.633); catalogued as COSV56045011; called by muse, mutect2
- CSMD3 | c.6755C>T p.P2252L (on ENST00000297405 / NM_001363185.1; = p.P2148L on NM_052900.3) | Missense Mutation (SNP) | VAF 30/284 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV52189315, COSV52308945; called by muse, mutect2, varscan2
- CTNND2 | c.1052C>G p.S351C | Missense Mutation (SNP) | VAF 33/223 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs761753748; called by muse, mutect2, varscan2
- CTTNBP2 | c.3514C>G p.L1172V | Missense Mutation (SNP) | VAF 16/203 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747542649; called by muse, mutect2
- CXXC1 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV99496034; called by muse, mutect2, varscan2
- CYP3A5 | c.1332G>A p.M444I | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV56121287; called by muse, mutect2
- DCAF4L2 | c.529C>A p.L177I | Missense Mutation (SNP) | VAF 35/318 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as COSV60480617; called by muse, mutect2, varscan2
- DDX60L | c.199C>G p.L67V | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.233); catalogued as COSV52719353; called by muse, mutect2
- DENND3 | c.1314-1G>A p.X438_splice | Splice Site (SNP) | VAF 9/110 reads (8%) | catalogued as rs1253513964; called by muse, mutect2
- DOCK11 | c.807G>C p.K269N | Missense Mutation (SNP) | VAF 10/215 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV52238533; called by muse, mutect2
- DUS3L | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs755658465; called by muse, mutect2, varscan2
- EDN3 | c.35C>A p.T12K | Missense Mutation (SNP) | VAF 56/337 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV61108606; called by muse, mutect2, varscan2
- EPN1 | c.1342C>G p.L448V (on ENST00000270460 / NM_001321263.1; = p.L422V on NM_013333.3) | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.207); catalogued as COSV50036760; called by muse, mutect2
- ESPNL | c.2845G>T p.G949W | Missense Mutation (SNP) | VAF 60/212 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as COSV58033164; called by muse, mutect2, varscan2
- EVC | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 16/362 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV53834795; called by muse, mutect2
- EVC | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 34/575 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.359); catalogued as rs749475050, COSV53833008, COSV53836029; called by muse, mutect2
- EXOC3L1 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.045); catalogued as rs1260336885, COSV52045084, COSV52046130; called by muse, mutect2, varscan2
- FAM160A2 | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 23/415 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV56412579; called by muse, mutect2
- FAM47C | c.2273G>A p.R758H | Missense Mutation (SNP) | VAF 24/450 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.151); catalogued as rs376888720, COSV63726995; called by muse, mutect2
- FBF1 | c.2068G>T p.E690* (on ENST00000586717; = p.E704* on NM_001319193.1) | Nonsense Mutation (SNP) | VAF 15/186 reads (8%) | catalogued as COSV59867524; called by muse, mutect2
- FGG | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 23/272 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM960659; called by muse, mutect2
- FIGLA | c.564C>A p.H188Q | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100189755; called by muse, mutect2
- FNDC3B | c.3445G>A p.V1149I | Missense Mutation (SNP) | VAF 33/331 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1361288526; called by muse, mutect2, varscan2
- FOXO4 | c.1181C>A p.P394Q | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV58575215; called by muse, mutect2
- FRMD4B | c.1057C>T p.Q353* | Nonsense Mutation (SNP) | VAF 13/145 reads (9%) | catalogued as COSV101273351; called by muse, mutect2
- GABRR1 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 42/383 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs185436805; called by muse, mutect2, varscan2
- GFPT1 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61946637; called by muse, mutect2
- GPC6 | c.714C>T p.V238= | Splice Region (SNP) | VAF 20/246 reads (8%) | catalogued as COSV100987977; called by muse, mutect2
- GPR157 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs1352594815, COSV66233227; called by muse, mutect2
- GPR158 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1293761350; called by muse, mutect2, varscan2
- H3C13 | c.258G>C p.Q86H | Missense Mutation (SNP) | VAF 22/548 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.437); catalogued as rs1277772195; called by muse, mutect2
- HGH1 | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 30/562 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); catalogued as rs1023725828; called by muse, mutect2
- HIGD1C | c.71G>C p.R24T | Missense Mutation (SNP) | VAF 16/219 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1023636414; called by muse, mutect2
- IER5 | c.886G>T p.E296* | Nonsense Mutation (SNP) | VAF 26/553 reads (5%) | catalogued as COSV100849649; called by muse, mutect2
- IL21R | c.1580C>A p.P527H | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV100560652; called by muse, mutect2, varscan2
- IRAG1 | c.155C>G p.A52G | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.46); catalogued as COSV101351098; called by muse, mutect2, varscan2
- IRF2BPL | c.1179G>T p.K393N | Missense Mutation (SNP) | VAF 12/221 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53146637; called by muse, mutect2
- KHDRBS1 | c.406G>C p.D136H | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs1437132344; called by muse, mutect2
- KIAA2026 | c.3377C>T p.P1126L | Missense Mutation (SNP) | VAF 27/262 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs368437749; called by muse, mutect2, varscan2
- KIF26B | c.3601G>A p.V1201I | Missense Mutation (SNP) | VAF 35/282 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as rs565300410; called by muse, mutect2, varscan2
- KRTAP26-1 | c.241G>C p.G81R | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs766339111, COSV62128543; called by muse, mutect2, varscan2
- LDHB | c.86T>C p.V29A | Missense Mutation (SNP) | VAF 55/314 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.89); catalogued as COSV63365018; called by muse, mutect2, varscan2
- LMTK2 | c.484G>T p.V162L | Missense Mutation (SNP) | VAF 25/266 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.787); catalogued as COSV51989516, COSV51992815; called by muse, mutect2, varscan2
- LPA | c.2794G>A p.E932K | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1189864114; called by muse, mutect2
- LRFN5 | c.395A>T p.N132I | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53257661; called by muse, mutect2, varscan2
- MAP3K1 | c.1803G>C p.E601D | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV68123470; called by muse, mutect2
- MAPK4 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 18/213 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.288); catalogued as COSV68543532; called by muse, mutect2
- MASP1 | c.1061C>A p.T354K | Missense Mutation (SNP) | VAF 34/311 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV51459038, COSV51462770; called by muse, varscan2
- MGA | c.3439G>T p.E1147* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as COSV54962409; called by muse, mutect2
- MICAL1 | c.645C>G p.I215M | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1320460578; called by muse, mutect2, varscan2
- MME | c.1432G>C p.E478Q | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV64710240; called by muse, mutect2
- MMP3 | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as rs1312012736; called by muse, mutect2
- MYO9B | c.2051G>A p.R684H | Missense Mutation (SNP) | VAF 22/482 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1256773188, COSV68278285; called by muse, mutect2
- MYOF | c.267G>T p.K89N | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV100826024; called by muse, mutect2
- MYOM1 | c.1790G>A p.R597Q | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1195563883; called by muse, mutect2
- MYRIP | c.794C>A p.P265H | Missense Mutation (SNP) | VAF 40/402 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV100218351; called by muse, mutect2
- NAALADL2 | c.124C>A p.Q42K | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.679); catalogued as rs1299415070, COSV70794948, COSV70795297; called by muse, mutect2, varscan2
- NAIP | c.415G>T p.D139Y | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV52001204; called by muse, mutect2
- NCOA5 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 24/508 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV51645020; called by muse, mutect2
- NELL2 | c.2386C>T p.L796F | Missense Mutation (SNP) | VAF 16/275 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs986658381, COSV100419941, COSV100420856; called by muse, mutect2
- NEU1 | c.787G>C p.D263H | Missense Mutation (SNP) | VAF 35/602 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs776384857; called by muse, mutect2
- NINL | c.3074A>T p.H1025L | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.018); catalogued as COSV54006483; called by muse, mutect2, varscan2
- NLRC3 | c.594C>A p.F198L | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.605); catalogued as rs1244683454; called by muse, mutect2, varscan2
- NUP155 | c.3427G>A p.E1143K (on ENST00000231498 / NM_153485.3; = p.E1084K on NM_004298.4) | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51533572; called by muse, mutect2
- OAZ1 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 39/263 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs969846397; called by muse, mutect2, varscan2
- OR2B11 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 112/361 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs576798914; called by muse, mutect2, varscan2
- OR2T12 | c.264G>T p.K88N | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100527458; called by muse, mutect2, varscan2
- OR2W3 | c.686G>T p.R229L | Missense Mutation (SNP) | VAF 60/431 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs750858075, COSV64455944, COSV64458463; called by muse, mutect2, varscan2
- OR4A5 | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.034); catalogued as rs756151380; called by muse, mutect2
- OR6B3 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757902043, COSV100097414; called by muse, mutect2
- PASD1 | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 9/184 reads (5%) | catalogued as COSV100949083; called by muse, mutect2
- PCDH11X | c.92G>T p.R31L | Missense Mutation (SNP) | VAF 48/467 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); catalogued as COSV53454712; called by muse, mutect2, varscan2
- PCSK4 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs568208587; called by muse, mutect2, varscan2
- PHLDB2 | c.3361G>C p.D1121H (on ENST00000393925 / NM_001134439.2; = p.D1078H on NM_145753.2) | Missense Mutation (SNP) | VAF 33/293 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67316007; called by muse, mutect2, varscan2
- PIEZO2 | c.1327G>T p.D443Y | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57453987; called by muse, mutect2, varscan2
- PLAT | c.804-1G>C p.X268_splice | Splice Site (SNP) | VAF 23/242 reads (10%) | catalogued as rs1342662073; called by muse, mutect2
- PLCB2 | c.2870+7C>A | Splice Region (SNP) | VAF 21/153 reads (14%) | catalogued as rs1411347375; called by muse, mutect2, varscan2
- PPFIA2 | c.3012G>T p.W1004C | Missense Mutation (SNP) | VAF 20/374 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61058403; called by muse, mutect2
- PRSS23 | c.632C>G p.S211* | Nonsense Mutation (SNP) | VAF 10/111 reads (9%) | catalogued as COSV54706663; called by muse, mutect2
- PTBP1 | c.968C>T p.A323V (on ENST00000349038 / NM_031991.4; = p.A349V on NM_002819.5) | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1480575187; called by muse, mutect2, varscan2
- PTPRT | c.3971G>T p.R1324L | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV62035398; called by muse, mutect2, varscan2
- PTPRT | c.3829G>A p.E1277K | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.566); catalogued as rs896375033; called by muse, mutect2
- RAC1 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 35/344 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.111); catalogued as COSV61824323; called by muse, mutect2
- RAI1 | c.2116C>G p.L706V | Missense Mutation (SNP) | VAF 88/616 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); catalogued as rs759197176; called by muse, mutect2, varscan2
- RASEF | c.259G>C p.D87H | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.094); catalogued as rs1255495026; called by muse, mutect2, varscan2
- RBM10 | c.2351A>T p.H784L | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61308125; called by muse, mutect2, varscan2
- REG3G | c.146C>A p.S49Y | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV55450544, COSV55450874; called by muse, mutect2, varscan2
- RGS20 | c.763G>C p.E255Q (on ENST00000297313 / NM_170587.4; = p.E108Q on NM_003702.4) | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV52017459, COSV99392151; called by muse, mutect2
- RNF168 | c.209C>G p.S70C | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as rs746582968, COSV100534945; called by muse, mutect2
- RNPS1 | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV57046249; called by muse, mutect2
- RREB1 | c.4862G>T p.G1621V | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as rs984836575; called by muse, mutect2, varscan2
- RTN4 | c.2156C>T p.S719L | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1463692212; called by muse, mutect2
- SCN11A | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs1402458245, COSV56568195; called by muse, varscan2
- SEMA3B | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV100312703; called by muse, mutect2, varscan2
- SF3B1 | c.677A>G p.H226R | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.599); catalogued as rs1487086972; called by muse, mutect2
- SFN | c.228G>C p.E76D | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV59432930; called by muse, mutect2
- SGCG | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 53/451 reads (12%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.715); catalogued as CM002106, COSV54556424; called by muse, mutect2, varscan2
- SIK2 | c.1864G>C p.E622Q | Missense Mutation (SNP) | VAF 11/233 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.663); catalogued as rs1301905897; called by muse, mutect2
- SLC35E1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs989936448; called by muse, mutect2
- SLC38A5 | c.857C>A p.S286Y | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV58334897; called by muse, mutect2
- SLC4A1AP | c.1135G>C p.D379H | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1249104576, COSV58135549; called by muse, mutect2, varscan2
- SLC4A3 | c.307G>T p.A103S | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV56098037; called by muse, mutect2, varscan2
- SLC6A5 | c.2319G>T p.M773I | Missense Mutation (SNP) | VAF 40/345 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV100116957; called by muse, mutect2, varscan2
- SLC9C1 | c.3400G>C p.E1134Q | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); catalogued as COSV59886127; called by muse, mutect2
- SMG1 | c.9212C>G p.S3071C | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV67175264; called by muse, mutect2
- SPTA1 | c.3192C>A p.Y1064* | Nonsense Mutation (SNP) | VAF 16/362 reads (4%) | catalogued as COSV100934111, COSV100934153; called by muse, mutect2
- SRCAP | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 26/229 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.027); catalogued as rs753339410, COSV52683494; called by muse, mutect2, varscan2
- SRCAP | c.8164C>T p.R2722C | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1399398123, COSV99349048; called by muse, mutect2
- SRRM2 | c.2596A>G p.T866A | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs113836515; called by muse, mutect2, varscan2
- STRN4 | c.1307C>T p.S436L | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99623825; called by muse, mutect2
- TBX15 | c.679G>A p.D227N (on ENST00000369429 / NM_001330677.2; = p.D121N on NM_152380.3) | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99254772, COSV99254967; called by muse, mutect2
- TEX55 | c.1611G>C p.*537Yext*14 | Nonstop Mutation (SNP) | VAF 12/260 reads (5%) | catalogued as COSV55210334; called by muse, mutect2
- TFAP2D | c.1096C>A p.P366T | Missense Mutation (SNP) | VAF 24/410 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV99148318; called by muse, mutect2
- TGM6 | c.1892C>A p.P631H | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99171767; called by muse, mutect2, varscan2
- TMC1 | c.1348C>G p.L450V | Missense Mutation (SNP) | VAF 28/354 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV52775402; called by muse, mutect2
- TMEM204 | c.101C>A p.T34K | Missense Mutation (SNP) | VAF 22/233 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.185); catalogued as COSV54151948; called by muse, mutect2, varscan2
- TNIP3 | c.251G>C p.R84T | Missense Mutation (SNP) | VAF 22/504 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV50249651; called by muse, mutect2
- TRAF3IP1 | c.1378C>T p.R460W | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1300880230; called by muse, mutect2
- TRPM2 | c.4098G>C p.K1366N | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.426); catalogued as COSV55968008; called by muse, mutect2
- TSC2 | c.3526C>T p.P1176S | Missense Mutation (SNP) | VAF 45/399 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.036); catalogued as rs1326077397; ClinVar: likely benign; called by muse, mutect2, varscan2
- TSEN15 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV62294375; called by muse, mutect2
- TSEN54 | c.1284G>C p.Q428H | Missense Mutation (SNP) | VAF 24/573 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); catalogued as COSV51344355; called by muse, mutect2
- TSPEAR | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.009); catalogued as rs1326762769, COSV100552399; called by muse, mutect2, varscan2
- TTLL5 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs369997391; called by muse, mutect2, varscan2
- UBR2 | c.4786G>A p.E1596K | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65749843; called by muse, mutect2
- UGT1A6 | c.616del p.S206Pfs*38 | Frame Shift Del (DEL) | VAF 23/136 reads (17%) | catalogued as rs779391112; called by mutect2, pindel, varscan2
- UNC79 | c.5913G>A p.M1971I (on ENST00000393151 / NM_001346218.2; = p.M1794I on NM_020818.5) | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as rs1566830194; called by muse, mutect2
- VSIG10 | c.1505G>A p.R502K | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); catalogued as COSV100821338, COSV99075647; called by muse, mutect2
- VSIG10L | c.1295C>A p.S432* | Nonsense Mutation (SNP) | VAF 9/110 reads (8%) | catalogued as COSV58536043; called by muse, mutect2
- ZNF713 | c.539C>G p.S180* (on ENST00000633730 / NM_001366796.2; = p.S193* on NM_182633.3) | Nonsense Mutation (SNP) | VAF 15/253 reads (6%) | catalogued as rs1456071483; called by muse, mutect2
- ZNF831 | c.3875G>T p.R1292M | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1227011834; called by muse, mutect2, varscan2
- ZNF90 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.313); catalogued as COSV69003015; called by muse, mutect2
- ABHD16A | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ACSL6 | c.1055C>T p.S352L (on ENST00000379240; = p.S377L on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/220 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- ADAMTS2 | c.2959-6C>A | Splice Region (SNP) | VAF 68/358 reads (19%) | called by muse, mutect2, varscan2
- AFF2 | c.1916G>T p.S639I | Missense Mutation (SNP) | VAF 17/272 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); called by muse, mutect2
- AKAP12 | c.4336C>A p.P1446T | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.057); called by muse, mutect2
- AMPD3 | c.2168G>A p.G723E (on ENST00000396553 / NM_001025389.2; = p.G732E on NM_000480.3) | Missense Mutation (SNP) | VAF 14/273 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANK2 | c.9838G>A p.E3280K | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- ANKMY1 | c.554C>G p.S185C | Missense Mutation (SNP) | VAF 43/797 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- ANKRD36 | c.4744A>T p.T1582S | Missense Mutation (SNP) | VAF 55/610 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); called by muse, mutect2
- ANKRD36B | c.625A>G p.I209V | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0.394); called by muse, mutect2
- APBB1 | c.123G>T p.Q41H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- APC2 | c.2690G>T p.G897V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARAF | c.524C>A p.P175H | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGAP11B | c.54C>G p.F18L | Missense Mutation (SNP) | VAF 11/315 reads (3%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- ARHGAP45 | c.2875C>T p.Q959* | Nonsense Mutation (SNP) | VAF 18/432 reads (4%) | called by muse, mutect2
- ARL14EP | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 16/370 reads (4%) | called by muse, mutect2
- ARPC3 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 41/482 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATP2B2 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- ATP6V1D | c.361C>G p.L121V | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- BAHCC1 | c.4687A>T p.S1563C | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- BBX | c.2163G>T p.K721N | Missense Mutation (SNP) | VAF 30/304 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- BEST2 | c.282G>T p.W94C | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BHLHE40 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 22/376 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.024); called by muse, mutect2
- BICD1 | c.2120C>T p.A707V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BNC1 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.116); called by muse, mutect2
- BRD9 | c.525G>A p.M175I | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.316); called by muse, mutect2
- BRF2 | c.713A>G p.Q238R | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTBD8 | c.1607G>T p.G536V (on ENST00000636805 / NM_001376131.1; = p.G23V on NM_015237.4) | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- C2CD2 | c.845-2A>G p.X282_splice | Splice Site (SNP) | VAF 18/208 reads (9%) | called by muse, mutect2
- C4orf54 | c.4567C>T p.Q1523* | Nonsense Mutation (SNP) | VAF 13/208 reads (6%) | called by muse, mutect2
- CACNA1S | c.4739C>A p.A1580D | Missense Mutation (SNP) | VAF 45/388 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- CACNA1S | c.1806dup p.A603Sfs*77 | Frame Shift Ins (INS) | VAF 53/461 reads (11%) | called by mutect2, pindel, varscan2
- CADPS | c.507G>C p.Q169H | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2
- CAMK1G | c.577C>A p.Q193K | Missense Mutation (SNP) | VAF 26/211 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- CAMTA2 | c.2622G>A p.M874I | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- CASK | c.2632G>C p.E878Q (on ENST00000378163 / NM_001367721.1; = p.E873Q on NM_003688.3) | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CASP8AP2 | c.2552G>A p.R851K | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- CBFB | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); called by muse, mutect2
- CCDC157 | c.943G>C p.E315Q | Missense Mutation (SNP) | VAF 20/368 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, mutect2
- CCNP | c.311C>T p.T104I | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- CCR4 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 17/224 reads (8%) | SIFT tolerated (0.28); PolyPhen probably damaging (1); called by muse, mutect2
- CCT6A | c.1560G>T p.E520D | Missense Mutation (SNP) | VAF 42/381 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2
- CD300LB | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 28/369 reads (8%) | called by muse, mutect2
- CDH8 | c.1279T>A p.F427I | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2
- CDS1 | c.1342C>T p.H448Y | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.61); called by muse, mutect2
- CELF1 | c.823C>G p.Q275E (on ENST00000358597 / NM_001376422.1; = p.Q271E on NM_006560.4 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/173 reads (5%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.585); called by muse, mutect2
- CERT1 | c.708G>T p.W236C (on ENST00000405807 / NM_001130105.1; = p.W108C on NM_005713.3) | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CFAP20DC | c.2007G>T p.M669I (on ENST00000482387 / NM_001351530.2; = p.M418I on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/267 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CFAP44 | c.5109C>G p.I1703M | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- CFAP46 | c.854T>C p.I285T | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.3); called by muse, mutect2
- CILP2 | c.798C>G p.F266L | Missense Mutation (SNP) | VAF 22/287 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2
- CLASRP | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- CLK1 | c.1206G>C p.M402I | Missense Mutation (SNP) | VAF 11/212 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2
- CMPK1 | c.139G>T p.G47C | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL4A5 | c.3841A>T p.K1281* | Nonsense Mutation (SNP) | VAF 35/294 reads (12%) | called by muse, mutect2, varscan2
- COL6A2 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 13/150 reads (9%) | called by muse, mutect2
- CPAMD8 | c.3233C>G p.S1078C (on ENST00000651564; = p.S1031C on NM_015692.5) | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CRMP1 | c.543C>G p.L181= | Splice Region (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- CSMD1 | c.3690C>G p.I1230M (on ENST00000520002; = p.I1229M on NM_033225.6) | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); called by muse, mutect2
- CSMD3 | c.4336G>T p.E1446* (on ENST00000297405 / NM_001363185.1; = p.E1342* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 15/152 reads (10%) | called by muse, mutect2, varscan2
- CTNND1 | c.443_444del p.V148Dfs*24 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by pindel, varscan2
- CYP11B1 | c.1025A>T p.Q342L | Missense Mutation (SNP) | VAF 23/251 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CYP7A1 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- DAGLA | c.2428C>T p.H810Y | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.068); called by muse, mutect2
- DCHS1 | c.6560A>T p.E2187V | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- DDI2 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.423); called by muse, mutect2
- DDX1 | c.393G>A p.G131= | Splice Region (SNP) | VAF 14/206 reads (7%) | called by muse, mutect2
- DLC1 | c.97C>T p.H33Y | Missense Mutation (SNP) | VAF 36/271 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DNAJB9 | c.48G>A p.M16I | Missense Mutation (SNP) | VAF 14/251 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- DSPP | c.2419A>G p.S807G | Missense Mutation (SNP) | VAF 62/702 reads (9%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.071); called by muse, mutect2
- DYM | c.596A>T p.H199L | Missense Mutation (SNP) | VAF 21/279 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2
- DYNC1H1 | c.12878A>G p.D4293G | Missense Mutation (SNP) | VAF 41/415 reads (10%) | SIFT tolerated (0.9); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DYSF | c.3392C>G p.S1131C | Missense Mutation (SNP) | VAF 66/357 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DZIP3 | c.1930T>C p.S644P | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- EIF2B4 | c.1243A>T p.M415L (on ENST00000347454 / NM_001034116.2; = p.M414L on NM_015636.3) | Missense Mutation (SNP) | VAF 11/236 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.055); called by muse, mutect2
- EIF3D | c.1507G>C p.E503Q | Missense Mutation (SNP) | VAF 60/414 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- ELAVL1 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 13/332 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.033); called by muse, mutect2
- EPG5 | c.2793dup p.A932Cfs*11 | Frame Shift Ins (INS) | VAF 16/157 reads (10%) | called by mutect2, pindel, varscan2
- EPG5 | c.571G>T p.V191L | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.022); called by muse, mutect2
- EPHA5 | c.1164C>A p.D388E | Missense Mutation (SNP) | VAF 35/221 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHA6 | c.2992T>C p.S998P | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.69); called by muse, mutect2
- EPPIN-WFDC6 | c.496G>T p.G166* | Nonsense Mutation (SNP) | VAF 16/228 reads (7%) | called by muse, mutect2
- ERCC8 | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2
- EXOC2 | c.1675C>A p.H559N | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- EXOC3L2 | c.1646C>A p.S549Y | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by mutect2, varscan2
- FAM240A | c.190G>C p.E64Q (on ENST00000444264; = p.E58Q on NM_001195442.2) | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- FAM83C | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.211); called by muse, mutect2
- FANCM | c.5072A>G p.N1691S | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.024); called by muse, mutect2
- FASN | c.3066G>T p.W1022C | Missense Mutation (SNP) | VAF 23/448 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FBN2 | c.7090G>A p.E2364K | Missense Mutation (SNP) | VAF 16/291 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.516); called by muse, mutect2
- FCGBP | c.6613G>T p.G2205C | Missense Mutation (SNP) | VAF 70/1112 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- FGD1 | c.1075C>A p.L359M | Missense Mutation (SNP) | VAF 10/217 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.054); called by muse, mutect2
- FTSJ1 | c.165G>A p.W55* | Nonsense Mutation (SNP) | VAF 18/346 reads (5%) | called by muse, mutect2
- GATAD2A | c.1732A>T p.S578C | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- GCOM1 | c.473A>T p.D158V | Missense Mutation (SNP) | VAF 35/364 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- GDF10 | c.534del p.Q179Rfs*67 | Frame Shift Del (DEL) | VAF 9/54 reads (17%) | called by mutect2, pindel
- GFAP | c.467A>T p.Q156L | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2
- GIMAP4 | c.317G>T p.C106F | Missense Mutation (SNP) | VAF 35/256 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GJA4 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GMCL1 | c.1547G>C p.*516Sext*2 | Nonstop Mutation (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- GNAI2 | c.63G>C p.K21N | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.598); called by muse, mutect2
- GPR12 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 52/334 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR62 | c.599G>C p.R200P | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- GPRASP1 | c.1349G>T p.G450V | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.006); called by muse, mutect2
- GRK1 | c.1325G>C p.R442T | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.311); called by muse, mutect2
- GTDC1 | c.1357G>C p.E453Q (on ENST00000344850 / NM_001354361.1; = p.E368Q on NM_024659.6 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- GTF3C1 | c.5101G>T p.G1701* | Nonsense Mutation (SNP) | VAF 15/79 reads (19%) | called by muse, mutect2, varscan2
- GYPC | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 17/364 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.033); called by muse, mutect2
- HERC2 | c.2711G>T p.R904L | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- HPS1 | c.1924G>T p.G642* | Nonsense Mutation (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2, varscan2
- HPS1 | c.985C>T p.Q329* | Nonsense Mutation (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- HS6ST2 | c.1175G>C p.R392P | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HSPB3 | c.118C>A p.P40T | Missense Mutation (SNP) | VAF 19/304 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IER5 | c.786G>C p.E262D | Missense Mutation (SNP) | VAF 26/420 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.019); called by muse, mutect2
- IFT172 | c.1218G>C p.E406D | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.019); called by muse, mutect2
- IGKV3-7 | c.172C>A p.Q58K | Missense Mutation (SNP) | VAF 22/439 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- IMMP2L | c.189C>G p.H63Q | Missense Mutation (SNP) | VAF 15/390 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.404); called by muse, mutect2
- KBTBD7 | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 20/569 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.741); called by muse, mutect2
- KCNH7 | c.958G>C p.D320H | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KCTD9 | c.589C>T p.H197Y | Missense Mutation (SNP) | VAF 18/285 reads (6%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.838); called by muse, mutect2
- KIAA1109 | c.3172C>A p.Q1058K | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.761); called by muse, mutect2
- KIR2DL1 | c.1045T>C p.*349Rext*11 | Nonstop Mutation (SNP) | VAF 28/372 reads (8%) | called by muse, mutect2
- KIR2DS4 | c.295A>G p.R99G | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- KIR3DX1 | n.1183-3C>G | Splice Region (SNP) | VAF 14/304 reads (5%) | called by muse, mutect2
- KLHL31 | c.256G>T p.V86F | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- KLHL6 | c.1083G>C p.E361D | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.352); called by muse, mutect2
- KLK11 | c.837G>A p.M279I (on ENST00000594768 / NM_144947.3; = p.M247I on NM_006853.3) | Missense Mutation (SNP) | VAF 16/359 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.014); called by muse, mutect2
- KPRP | c.277C>A p.Q93K | Missense Mutation (SNP) | VAF 19/464 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.013); called by muse, mutect2
- KRT1 | c.685C>A p.P229T | Missense Mutation (SNP) | VAF 18/476 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2
- LAMA5 | c.10020dup p.Y3341Lfs*21 | Frame Shift Ins (INS) | VAF 11/84 reads (13%) | called by mutect2, pindel, varscan2
- LASP1 | c.455A>G p.Y152C | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); called by muse, mutect2
- LRRC7 | c.1734G>A p.M578I (on ENST00000651989 / NM_001370785.2; = p.M545I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- LUZP2 | c.937-2A>T p.X313_splice | Splice Site (SNP) | VAF 18/152 reads (12%) | called by muse, mutect2
- MAP7 | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAPT | c.1799G>T p.S600I (on ENST00000262410 / NM_001377265.1; = p.S208I on NM_005910.5) | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MARCHF1 | c.277C>A p.L93I (on ENST00000274056; = p.L76I on NM_017923.4) | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- MBTPS2 | c.424G>T p.V142L | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2
- MCC | c.637G>C p.E213Q | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.932); called by muse, mutect2
- MCM4 | c.394G>T p.D132Y | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- MCPH1 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 12/183 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- MDP1 | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); called by muse, mutect2
- MED24 | c.227C>G p.S76C | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- MEGF10 | c.859G>T p.G287W | Missense Mutation (SNP) | VAF 42/262 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- METTL2B | c.348C>G p.F116L | Missense Mutation (SNP) | VAF 67/474 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, varscan2
- MMS22L | c.3095G>A p.G1032E | Missense Mutation (SNP) | VAF 28/273 reads (10%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- MPEG1 | c.643C>A p.L215I | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MROH2A | c.2012A>T p.N671I | Missense Mutation (SNP) | VAF 47/284 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- MSX1 | c.721G>T p.A241S | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); called by muse, mutect2
- MTMR6 | c.364C>G p.L122V | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- MUC16 | c.38468C>A p.P12823H | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.526); called by muse, varscan2
- MUC5B | c.6347C>G p.S2116C | Missense Mutation (SNP) | VAF 22/427 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); called by muse, mutect2
- MYH11 | c.5127G>C p.E1709D | Missense Mutation (SNP) | VAF 24/390 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.439); called by muse, mutect2
- MYH7B | c.549G>T p.K183N | Missense Mutation (SNP) | VAF 41/271 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- NAV3 | c.2906C>A p.P969H | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.115); called by muse, mutect2
- NAV3 | c.4406C>T p.S1469F | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.333); called by muse, mutect2
- NBEA | c.8776G>T p.G2926C | Missense Mutation (SNP) | VAF 27/218 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCAPG2 | c.3230G>C p.G1077A | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2
- NDRG1 | c.847C>G p.L283V | Missense Mutation (SNP) | VAF 19/427 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- NDUFB9 | c.333G>C p.E111D | Missense Mutation (SNP) | VAF 24/380 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.025); called by muse, mutect2
- NEFH | c.654G>C p.K218N | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2
- NKAIN4 | c.206C>A p.A69E | Missense Mutation (SNP) | VAF 45/274 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NLRP8 | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- NOXRED1 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- NPHS1 | c.2437G>T p.A813S | Missense Mutation (SNP) | VAF 30/269 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- NQO2 | c.68A>C p.K23T | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.701); called by muse, mutect2
- NRCAM | c.299del p.G100Afs*6 (on ENST00000379028 / NM_001371124.1; = p.G94Afs*6 on NM_005010.4 and 21 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 22/216 reads (10%) | called by mutect2, pindel
- NTN3 | c.997C>A p.R333S | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- NUB1 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NXF1 | c.928G>C p.D310H | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- OAF | c.750G>C p.K250N | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OPN1LW | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 23/839 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- OR11H12 | c.413A>T p.Y138F | Missense Mutation (SNP) | VAF 36/914 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.132); called by muse, mutect2
- OR11L1 | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- OR2L8 | c.542C>A p.P181Q | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- OR2T4 | c.496G>C p.V166L | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2
- OR4K2 | c.664C>A p.L222M | Missense Mutation (SNP) | VAF 38/438 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2
- OR5AP2 | c.841T>A p.S281T | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR8G2P | c.704C>A p.S235Y | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PAM | c.267G>C p.V89= | Splice Region (SNP) | VAF 9/210 reads (4%) | called by muse, mutect2
- PAPPA | c.3125T>A p.I1042N | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by mutect2, varscan2
- PCDH12 | c.1868C>T p.A623V | Missense Mutation (SNP) | VAF 17/387 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHB12 | c.330G>C p.M110I | Missense Mutation (SNP) | VAF 10/253 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.139); called by muse, mutect2
- PCDHGC5 | c.1912G>C p.D638H | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- PDE10A | c.1441C>A p.P481T | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PDE6C | c.881G>A p.W294* | Nonsense Mutation (SNP) | VAF 42/325 reads (13%) | called by muse, mutect2, varscan2
- PDHA1 | c.601C>T p.Q201* | Nonsense Mutation (SNP) | VAF 46/444 reads (10%) | called by muse, mutect2, varscan2
- PGRMC1 | c.160A>T p.S54C | Missense Mutation (SNP) | VAF 26/295 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.086); called by muse, mutect2
- PHF11 | c.605G>C p.R202T | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- PIEZO2 | c.1080+1G>T p.X360_splice | Splice Site (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- PKD1L2 | c.1120C>T p.Q374* | Nonsense Mutation (SNP) | VAF 10/166 reads (6%) | called by muse, mutect2
- PKP2 | c.1064G>C p.R355P | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.054); called by muse, mutect2
- PLXNA3 | c.4610G>C p.R1537P | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.559); called by muse, mutect2
- PLXND1 | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); called by muse, mutect2
- POLA1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- POTEF | c.2156C>A p.A719D | Missense Mutation (SNP) | VAF 55/561 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- PPIL1 | c.159C>A p.F53L | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- PPM1J | c.345G>C p.K115N | Missense Mutation (SNP) | VAF 24/309 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PPME1 | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 12/289 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.444); called by muse, mutect2
- PPP1R16B | c.1050C>A p.S350R | Missense Mutation (SNP) | VAF 45/214 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PSG3 | c.323T>G p.L108R | Missense Mutation (SNP) | VAF 43/317 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- PSMC3 | c.160-1G>C p.X54_splice | Splice Site (SNP) | VAF 14/204 reads (7%) | called by muse, mutect2
- PSMC6 | c.460G>A p.E154K (on ENST00000612399; = p.E140K on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.447); called by muse, mutect2
- PUM2 | c.2945A>T p.Q982L | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- RAB1B | c.190A>G p.T64A | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RAB3GAP2 | c.1111G>T p.A371S | Missense Mutation (SNP) | VAF 58/453 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- RACGAP1 | c.1435C>T p.H479Y | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, varscan2
- RAD54B | c.1117G>C p.E373Q | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAET1E | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.081); called by muse, mutect2
- RBM28 | c.1505A>T p.Q502L | Missense Mutation (SNP) | VAF 75/375 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- RCAN2 | c.103T>A p.W35R | Missense Mutation (SNP) | VAF 34/322 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- RELN | c.7607G>A p.G2536E | Missense Mutation (SNP) | VAF 27/365 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RGPD8 | c.2818C>T p.L940F | Missense Mutation (SNP) | VAF 34/721 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2
- RND2 | c.316C>G p.Q106E | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.069); called by muse, mutect2
- RPGR | c.2511C>G p.D837E (on ENST00000339363 / NM_001367249.1; = p.D632E on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/461 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.013); called by muse, mutect2
- RRP8 | c.1042G>T p.A348S | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- RTL1 | c.671T>C p.L224S | Missense Mutation (SNP) | VAF 11/202 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.326); called by muse, mutect2
- RTL9 | c.2425C>T p.P809S | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2
- RTN1 | c.1105G>T p.E369* | Nonsense Mutation (SNP) | VAF 22/290 reads (8%) | called by muse, mutect2
- SBF1 | c.5257G>A p.D1753N | Missense Mutation (SNP) | VAF 18/325 reads (6%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.691); called by muse, mutect2
- SCG2 | c.1746G>T p.R582S | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.519); called by muse, mutect2
- SDHAF4 | c.174dup p.D59* | Frame Shift Ins (INS) | VAF 16/130 reads (12%) | called by mutect2, pindel, varscan2
- SEMA3D | c.1508C>G p.S503* | Nonsense Mutation (SNP) | VAF 12/236 reads (5%) | called by muse, mutect2
- SFMBT2 | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2
- SFT2D2 | c.241A>T p.I81F | Missense Mutation (SNP) | VAF 33/266 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SH3RF2 | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 15/346 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2
- SHFL | c.107G>C p.G36A | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SHISA7 | c.1543C>A p.Q515K | Missense Mutation (SNP) | VAF 47/273 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- SI | c.5152C>T p.Q1718* | Nonsense Mutation (SNP) | VAF 50/395 reads (13%) | called by muse, mutect2, varscan2
- SIGLEC5 | c.1528C>A p.P510T | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- SLC10A3 | c.421G>A p.G141R | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC16A1 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2
- SLC38A7 | c.45G>C p.L15F | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- SLC6A6 | c.1450+1G>T p.X484_splice | Splice Site (SNP) | VAF 35/220 reads (16%) | called by muse, mutect2, varscan2
- SLFN13 | c.2125C>G p.H709D | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- SMG1 | c.9506C>T p.A3169V | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SNRK | c.290G>C p.G97A | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- SNRPE | c.250A>G p.I84V | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.019); called by muse, mutect2
- SORBS2 | c.100A>G p.T34A (on ENST00000284776 / NM_021069.5; = p.T80A on NM_003603.6) | Missense Mutation (SNP) | VAF 17/236 reads (7%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2
- SORCS2 | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SPACA1 | c.73C>A p.Q25K | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SPANXN1 | c.14C>A p.T5N | Missense Mutation (SNP) | VAF 75/378 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPATA2L | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.455); called by muse, mutect2
- SPATA46 | c.488C>G p.S163C | Missense Mutation (SNP) | VAF 18/417 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.723); called by muse, mutect2
- SPOCK3 | c.677A>T p.Q226L | Missense Mutation (SNP) | VAF 33/260 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- SRPX | c.1212G>C p.R404S | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SRRT | c.2535_2551del p.Y845* | Frame Shift Del (DEL) | VAF 11/111 reads (10%) | called by mutect2, pindel
- SRSF2 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 23/232 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- STARD9 | c.8909A>G p.H2970R | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.735); called by muse, mutect2
- SUN2 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SYCP2 | c.2969G>T p.S990I | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.06); called by muse, mutect2
- SYNE1 | c.23016G>T p.L7672F (on ENST00000367255 / NM_182961.4; = p.L7601F on NM_033071.3) | Missense Mutation (SNP) | VAF 22/350 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- SYNE1 | c.4800G>T p.Q1600H (on ENST00000367255 / NM_182961.4; = p.Q1607H on NM_033071.3) | Missense Mutation (SNP) | VAF 61/475 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SYNM | c.2749C>T p.H917Y | Missense Mutation (SNP) | VAF 22/572 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- SYT5 | c.562G>T p.G188C | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); called by mutect2, varscan2
- TADA2A | c.26-1G>A p.X9_splice | Splice Site (SNP) | VAF 13/91 reads (14%) | called by muse, varscan2
- TBC1D3L | c.1619T>A p.L540* | Nonsense Mutation (SNP) | VAF 23/770 reads (3%) | called by muse, mutect2
- TBC1D9B | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2
- TCTN1 | c.1651A>T p.I551F (on ENST00000551590 / NM_001173975.3; = p.I537F on NM_024549.6) | Missense Mutation (SNP) | VAF 28/384 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); called by muse, mutect2
- TDRD7 | c.3172G>A p.E1058K | Missense Mutation (SNP) | VAF 31/494 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2
- TENT2 | c.14C>G p.S5* | Nonsense Mutation (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- TGM1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 40/536 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.042); called by muse, mutect2
- THSD7A | c.3409C>A p.P1137T | Missense Mutation (SNP) | VAF 26/197 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- TIAM1 | c.2730G>T p.M910I | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM128 | c.446T>A p.L149* (on ENST00000382753 / NM_001297552.2; = p.L125* on NM_032927.3) | Nonsense Mutation (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2
- TNR | c.1097del p.G366Afs*93 | Frame Shift Del (DEL) | VAF 133/527 reads (25%) | called by mutect2, pindel, varscan2
- TNXB | c.5542G>A p.E1848K (on ENST00000647633; = p.E1601K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/253 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- TPR | c.5279C>G p.S1760C | Missense Mutation (SNP) | VAF 18/510 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); called by muse, mutect2
- TRIM39 | c.532A>T p.K178* | Nonsense Mutation (SNP) | VAF 18/315 reads (6%) | called by muse, mutect2
- TRIM69 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 26/398 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.449); called by muse, mutect2
- TRPV5 | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 34/289 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- TTC3 | c.6068C>G p.S2023C | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2
- TTF1 | c.1236G>C p.K412N | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.053); called by muse, mutect2
- UBASH3A | c.1926G>C p.K642N | Missense Mutation (SNP) | VAF 13/288 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.701); called by muse, mutect2
- UPF3B | c.106G>T p.G36W | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.748); called by muse, mutect2
- UXS1 | c.400G>T p.G134* | Nonsense Mutation (SNP) | VAF 25/171 reads (15%) | called by muse, mutect2, varscan2
- VCAM1 | c.125C>A p.S42Y | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.057); called by muse, mutect2
- VCPKMT | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 30/285 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- VNN1 | c.809C>A p.P270H | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2
- WDR48 | c.1244A>C p.Y415S | Missense Mutation (SNP) | VAF 10/197 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2
- WDR7 | c.1606G>T p.V536L | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- WWC2 | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 7/74 reads (9%) | called by muse, mutect2
- WWTR1 | c.156C>G p.F52L | Missense Mutation (SNP) | VAF 34/319 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- XIRP2 | c.1442G>T p.W481L (on ENST00000628543; = p.W656L on NM_152381.6) | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- YES1 | c.32G>T p.S11I | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2
- ZAN | c.713G>C p.G238A | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- ZNF121 | c.968C>T p.T323I | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- ZNF135 | c.405G>C p.W135C (on ENST00000313434 / NM_001289401.2; = p.W147C on NM_003436.4) | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- ZNF208 | c.3676A>T p.K1226* | Nonsense Mutation (SNP) | VAF 27/356 reads (8%) | called by muse, mutect2
- ZNF257 | c.787G>T p.G263C | Missense Mutation (SNP) | VAF 21/218 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- ZNF292 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 38/216 reads (18%) | called by muse, mutect2, varscan2
- ZNF536 | c.796G>T p.D266Y | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- ZNF711 | c.44C>A p.S15Y | Missense Mutation (SNP) | VAF 32/336 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.202); called by muse, mutect2
- ZNF711 | c.1443T>A p.C481* | Nonsense Mutation (SNP) | VAF 20/222 reads (9%) | called by muse, mutect2
- ZNF879 | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ABCD1 | c.1674C>T p.I558= | Silent (SNP) | VAF 27/420 reads (6%) | called by muse, mutect2
- ACMSD | c.822C>G p.L274= | Silent (SNP) | VAF 14/155 reads (9%) | called by muse, mutect2
- AMPD2 | c.1389C>T p.Y463= | Silent (SNP) | VAF 12/231 reads (5%) | called by muse, mutect2
- ANGPTL1 | c.1425C>G p.G475= | Silent (SNP) | VAF 31/212 reads (15%) | called by muse, mutect2, varscan2
- APOB | c.1461G>A p.L487= | Silent (SNP) | VAF 22/338 reads (7%) | called by muse, mutect2
- APOE | c.465C>T p.L155= | Silent (SNP) | VAF 15/334 reads (4%) | catalogued as rs1356159599; called by muse, mutect2
- ARX | c.792G>C p.R264= | Silent (SNP) | VAF 18/216 reads (8%) | called by muse, mutect2
- ATP13A3 | c.1350C>T p.I450= | Silent (SNP) | VAF 28/338 reads (8%) | catalogued as COSV99757624; called by muse, mutect2
- B4GALNT2 | c.402C>T p.F134= | Silent (SNP) | VAF 15/116 reads (13%) | called by muse, mutect2, varscan2
- BAP1 | c.648C>T p.L216= | Silent (SNP) | VAF 39/552 reads (7%) | catalogued as rs758650064; ClinVar: likely benign; called by muse, mutect2
- BNC2 | c.1284G>A p.R428= | Silent (SNP) | VAF 16/166 reads (10%) | called by muse, mutect2
- CABS1 | c.513T>A p.A171= | Silent (SNP) | VAF 8/163 reads (5%) | called by muse, mutect2
- CACNA1S | c.288C>A p.V96= | Silent (SNP) | VAF 66/454 reads (15%) | called by muse, mutect2, varscan2
- CACNG7 | c.24C>G p.A8= | Silent (SNP) | VAF 44/406 reads (11%) | called by muse, mutect2, varscan2
- CAPN2 | c.945G>C p.L315= | Silent (SNP) | VAF 11/228 reads (5%) | called by muse, mutect2
- CBR3 | c.63C>T p.I21= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs1253922034; called by muse, mutect2, varscan2
- CCDC157 | c.396G>T p.T132= | Silent (SNP) | VAF 6/44 reads (14%) | called by mutect2, varscan2
- CCDC66 | c.741C>T p.F247= (on ENST00000394672 / NM_001353147.1; = p.F213= on NM_001012506.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 17/205 reads (8%) | called by muse, mutect2
- CCT4 | c.24G>A p.R8= | Silent (SNP) | VAF 11/102 reads (11%) | called by muse, mutect2, varscan2
- CCZ1B | c.1293G>A p.V431= | Silent (SNP) | VAF 14/323 reads (4%) | called by muse, mutect2
- CDH4 | c.1365C>A p.T455= | Silent (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- CEACAM16 | c.468C>T p.P156= | Silent (SNP) | VAF 14/236 reads (6%) | called by muse, mutect2
- CFAP47 | c.2592C>T p.F864= | Silent (SNP) | VAF 10/134 reads (7%) | catalogued as COSV99934079; called by muse, mutect2
- CIT | c.2616C>T p.L872= | Silent (SNP) | VAF 22/275 reads (8%) | called by muse, mutect2
- CNOT1 | c.5682C>G p.L1894= | Silent (SNP) | VAF 7/136 reads (5%) | called by muse, mutect2
- CNTN2 | c.2076C>T p.G692= | Silent (SNP) | VAF 27/189 reads (14%) | called by muse, mutect2, varscan2
- COASY | c.1518C>T p.L506= | Silent (SNP) | VAF 13/246 reads (5%) | catalogued as COSV55900668; called by muse, mutect2
- CPAMD8 | c.3552C>T p.L1184= (on ENST00000651564; = p.L1137= on NM_015692.5) | Silent (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- CSRNP2 | c.213G>A p.V71= | Silent (SNP) | VAF 14/232 reads (6%) | called by muse, mutect2
- DCDC1 | c.3591G>T p.V1197= (on ENST00000597505 / NM_001367979.1; = p.V304= on NM_020869.3) | Silent (SNP) | VAF 42/446 reads (9%) | called by muse, mutect2
- DDR1 | c.1107G>A p.V369= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs765312737; called by muse, mutect2
- DKK3 | c.813C>A p.L271= | Silent (SNP) | VAF 14/89 reads (16%) | called by muse, mutect2, varscan2
- DLG5 | c.4236C>G p.L1412= | Silent (SNP) | VAF 15/229 reads (7%) | called by muse, mutect2
- DMGDH | c.228G>T p.V76= | Silent (SNP) | VAF 46/233 reads (20%) | called by muse, mutect2, varscan2
- DOCK2 | c.3012C>T p.I1004= | Silent (SNP) | VAF 24/144 reads (17%) | called by muse, mutect2, varscan2
- DOCK3 | c.1500C>T p.F500= | Silent (SNP) | VAF 14/165 reads (8%) | catalogued as COSV56550475; called by muse, mutect2
- DYNC2I1 | c.1350C>G p.P450= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as rs1262761344; called by muse, mutect2
- FBXO21 | c.1389G>C p.G463= (on ENST00000330622 / NM_033624.3; = p.G456= on NM_015002.3) | Silent (SNP) | VAF 28/290 reads (10%) | called by muse, mutect2
- FGL2 | c.900G>A p.L300= | Silent (SNP) | VAF 10/244 reads (4%) | catalogued as rs1453814475; called by muse, mutect2
- FLNA | c.2865C>T p.P955= | Silent (SNP) | VAF 18/298 reads (6%) | called by muse, mutect2
- FSIP2 | c.6609G>A p.K2203= | Silent (SNP) | VAF 21/139 reads (15%) | catalogued as rs757417967; called by muse, mutect2, varscan2
- FTCD | c.1362G>A p.L454= | Silent (SNP) | VAF 29/360 reads (8%) | called by muse, mutect2
- FUT10 | c.1296G>C p.R432= | Silent (SNP) | VAF 39/351 reads (11%) | called by muse, mutect2, varscan2
- GASK1B | c.804C>G p.L268= | Silent (SNP) | VAF 14/460 reads (3%) | called by muse, mutect2
- GBP3 | c.1129C>T p.L377= | Silent (SNP) | VAF 20/234 reads (9%) | called by muse, mutect2
- GFPT2 | c.1887C>A p.S629= | Silent (SNP) | VAF 40/191 reads (21%) | called by muse, mutect2, varscan2
- GNL3L | c.816G>A p.L272= | Silent (SNP) | VAF 10/218 reads (5%) | called by muse, mutect2
- GRM8 | c.600C>G p.S200= | Silent (SNP) | VAF 48/510 reads (9%) | called by muse, mutect2
- GUCY1A2 | c.1071G>T p.V357= | Silent (SNP) | VAF 10/115 reads (9%) | called by muse, mutect2
- HEATR5B | c.3531T>G p.L1177= | Silent (SNP) | VAF 36/252 reads (14%) | catalogued as rs1558751611; called by muse, mutect2, varscan2
- HIC2 | c.1728C>A p.L576= | Silent (SNP) | VAF 19/214 reads (9%) | catalogued as COSV101335586; called by muse, mutect2
- HPS6 | c.723G>A p.L241= | Silent (SNP) | VAF 32/446 reads (7%) | called by muse, mutect2
- HSPB7 | c.186C>A p.P62= | Silent (SNP) | VAF 32/200 reads (16%) | called by muse, mutect2, varscan2
- IGLV2-33 | c.111C>T p.V37= | Silent (SNP) | VAF 13/235 reads (6%) | called by muse, mutect2
- IGSF3 | c.1089C>T p.I363= | Silent (SNP) | VAF 12/270 reads (4%) | called by muse, mutect2
- IL17RE | c.1275G>A p.L425= | Silent (SNP) | VAF 12/236 reads (5%) | called by muse, mutect2
- IMPG1 | c.348C>A p.R116= | Silent (SNP) | VAF 24/173 reads (14%) | called by muse, mutect2, varscan2
- KDM5C | c.4380G>T p.R1460= | Silent (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- KIFC1 | c.243G>A p.Q81= | Silent (SNP) | VAF 13/184 reads (7%) | called by muse, mutect2
- KLHDC7A | c.150G>A p.G50= | Silent (SNP) | VAF 12/172 reads (7%) | catalogued as COSV101272728; called by muse, mutect2
- KRT24 | c.894G>A p.V298= | Silent (SNP) | VAF 8/140 reads (6%) | called by muse, mutect2
- LPAR3 | c.156C>A p.I52= | Silent (SNP) | VAF 35/342 reads (10%) | called by muse, mutect2
- LRCH3 | c.1923A>G p.T641= | Silent (SNP) | VAF 20/225 reads (9%) | called by muse, mutect2
- LRRC32 | c.1698C>G p.L566= | Silent (SNP) | VAF 28/384 reads (7%) | called by muse, mutect2
- LRRC4C | c.1215G>C p.V405= | Silent (SNP) | VAF 27/163 reads (17%) | called by muse, mutect2, varscan2
- LTB | c.609G>A p.T203= | Silent (SNP) | VAF 27/375 reads (7%) | called by muse, mutect2
- MAGEE2 | c.865C>T p.L289= | Silent (SNP) | VAF 11/221 reads (5%) | catalogued as COSV100973014; called by muse, mutect2
- MANBA | c.1017G>A p.L339= | Silent (SNP) | VAF 21/199 reads (11%) | called by muse, mutect2, varscan2
- MARCHF1 | c.276C>A p.P92= (on ENST00000274056; = p.P75= on NM_017923.4) | Silent (SNP) | VAF 17/110 reads (15%) | called by muse, mutect2, varscan2
- MBD5 | c.246G>A p.V82= | Silent (SNP) | VAF 18/447 reads (4%) | called by muse, mutect2
- MDC1 | c.2211C>T p.F737= | Silent (SNP) | VAF 24/265 reads (9%) | called by muse, mutect2
- MTMR7 | c.1710C>G p.T570= | Silent (SNP) | VAF 12/228 reads (5%) | called by muse, mutect2
- MYO19 | c.1062C>T p.I354= | Silent (SNP) | VAF 20/388 reads (5%) | called by muse, mutect2
- NEU1 | c.1026G>A p.V342= | Silent (SNP) | VAF 18/448 reads (4%) | catalogued as rs1332241624; called by muse, mutect2
- NFIB | c.787C>T p.L263= | Silent (SNP) | VAF 20/282 reads (7%) | called by muse, mutect2
- NUDT12 | c.117C>T p.L39= | Silent (SNP) | VAF 16/312 reads (5%) | called by muse, mutect2
- OR2L2 | c.792G>C p.L264= | Silent (SNP) | VAF 18/180 reads (10%) | catalogued as COSV63559601; called by muse, mutect2, varscan2
- OR4A16 | c.507C>T p.P169= | Silent (SNP) | VAF 23/154 reads (15%) | catalogued as rs769120876; called by muse, mutect2, varscan2
- PCDH7 | c.2259G>T p.V753= | Silent (SNP) | VAF 14/160 reads (9%) | called by muse, mutect2
- PCDHA1 | c.351C>T p.F117= | Silent (SNP) | VAF 13/224 reads (6%) | catalogued as rs1554117490, COSV65373297; called by muse, mutect2
- PEX6 | c.627G>C p.R209= | Silent (SNP) | VAF 21/269 reads (8%) | catalogued as COSV55105519; called by muse, mutect2
- PHKB | c.2394A>G p.P798= | Silent (SNP) | VAF 42/424 reads (10%) | called by muse, mutect2
- PKD2 | c.786G>T p.V262= | Silent (SNP) | VAF 16/323 reads (5%) | called by muse, mutect2
- PLEKHG4B | c.2901C>T p.L967= (on ENST00000283426; = p.L1323= on NM_052909.5) | Silent (SNP) | VAF 11/220 reads (5%) | called by muse, mutect2
- PLXNC1 | c.2478G>A p.L826= | Silent (SNP) | VAF 20/336 reads (6%) | called by muse, mutect2
- PMFBP1 | c.1275G>A p.L425= | Silent (SNP) | VAF 16/358 reads (4%) | called by muse, mutect2
- POLR3E | c.1797C>T p.F599= | Silent (SNP) | VAF 20/336 reads (6%) | called by muse, mutect2
- POSTN | c.927C>G p.L309= | Silent (SNP) | VAF 24/194 reads (12%) | catalogued as COSV101123281, COSV65714218; called by muse, mutect2, varscan2
- POTEF | c.2157C>G p.A719= | Silent (SNP) | VAF 54/553 reads (10%) | called by muse, mutect2, varscan2
- PPP1R15B | c.111G>T p.P37= | Silent (SNP) | VAF 22/524 reads (4%) | called by muse, mutect2
- PPP1R3F | c.1890G>T p.V630= | Silent (SNP) | VAF 12/196 reads (6%) | called by muse, mutect2
- PRSS16 | c.375G>A p.L125= | Silent (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
- R3HDM2 | c.2001G>T p.G667= | Silent (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- RALGDS | c.2094C>T p.L698= | Silent (SNP) | VAF 34/404 reads (8%) | called by muse, mutect2
- RNF213 | c.10258C>T p.L3420= | Silent (SNP) | VAF 16/402 reads (4%) | called by muse, mutect2
- RYR3 | c.12441T>C p.S4147= (on ENST00000389232; = p.S4148= on NM_001036.6) | Silent (SNP) | VAF 22/146 reads (15%) | catalogued as rs1450095392; called by muse, mutect2, varscan2
- SDHA | c.1578C>T p.F526= | Silent (SNP) | VAF 42/634 reads (7%) | catalogued as COSV99371765; called by muse, mutect2
- SECISBP2L | c.1050C>T p.C350= | Silent (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- SERPINA10 | c.12G>T p.V4= | Silent (SNP) | VAF 22/292 reads (8%) | called by muse, mutect2
- SERPINE2 | c.351G>A p.K117= | Silent (SNP) | VAF 22/313 reads (7%) | called by muse, mutect2
- SHROOM4 | c.1774C>T p.L592= | Silent (SNP) | VAF 29/356 reads (8%) | catalogued as rs782276885; called by muse, mutect2
- SLC16A1 | c.1500C>T p.V500= | Silent (SNP) | VAF 16/346 reads (5%) | called by muse, mutect2
- SLC45A4 | c.78G>A p.Q26= | Silent (SNP) | VAF 16/268 reads (6%) | catalogued as COSV70864271; called by muse, mutect2
- SOX21 | c.156G>A p.S52= | Silent (SNP) | VAF 32/503 reads (6%) | catalogued as COSV65375420; called by muse, mutect2
- SPATA19 | c.61C>T p.L21= | Silent (SNP) | VAF 12/121 reads (10%) | called by muse, mutect2, varscan2
- SPTBN4 | c.3213C>A p.G1071= | Silent (SNP) | VAF 13/91 reads (14%) | called by muse, mutect2, varscan2
- SRCAP | c.5703G>A p.L1901= | Silent (SNP) | VAF 11/101 reads (11%) | called by muse, mutect2, varscan2
- SULF2 | c.222C>T p.G74= | Silent (SNP) | VAF 53/340 reads (16%) | catalogued as rs983061029, COSV63413644; called by muse, mutect2, varscan2
- TANGO6 | c.1059C>A p.I353= | Silent (SNP) | VAF 21/241 reads (9%) | catalogued as rs368736182; called by muse, mutect2
- TENM2 | c.2649G>T p.R883= (on ENST00000518659 / NM_001122679.2; = p.R651= on NM_001080428.3) | Silent (SNP) | VAF 37/186 reads (20%) | called by muse, mutect2, varscan2
- TGS1 | c.2484G>A p.Q828= | Silent (SNP) | VAF 20/202 reads (10%) | called by muse, mutect2
- TREH | c.1254C>G p.L418= | Silent (SNP) | VAF 23/506 reads (5%) | called by muse, mutect2
- TRPV5 | c.1500C>A p.V500= | Silent (SNP) | VAF 30/244 reads (12%) | called by muse, mutect2, varscan2
- TSC2 | c.2799C>T p.F933= | Silent (SNP) | VAF 19/356 reads (5%) | called by muse, mutect2
- TUBGCP2 | c.738C>T p.F246= | Silent (SNP) | VAF 46/367 reads (13%) | catalogued as rs1221269955; called by muse, mutect2, varscan2
- UBR4 | c.13554G>A p.V4518= | Silent (SNP) | VAF 15/354 reads (4%) | called by muse, mutect2
- USP28 | c.3072G>T p.L1024= | Silent (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2, varscan2
- ZBTB47 | c.291G>A p.Q97= | Silent (SNP) | VAF 30/230 reads (13%) | called by muse, mutect2, varscan2
- ZFAND4 | c.1701C>T p.I567= | Silent (SNP) | VAF 14/210 reads (7%) | called by muse, mutect2
- ZFHX3 | c.7875C>T p.S2625= | Silent (SNP) | VAF 15/145 reads (10%) | catalogued as COSV51729697; called by muse, mutect2, varscan2
- ZFHX4 | c.8265T>A p.P2755= | Silent (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- ZNF292 | c.96G>A p.L32= | Silent (SNP) | VAF 41/223 reads (18%) | called by muse, mutect2, varscan2
- ZNF440 | c.882G>C p.T294= | Silent (SNP) | VAF 20/111 reads (18%) | catalogued as rs375520181; called by muse, mutect2, varscan2
- ZNF768 | c.1287C>T p.F429= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as COSV63322620; called by muse, mutect2, varscan2
- ZNF776 | c.1137G>T p.T379= | Silent (SNP) | VAF 17/97 reads (18%) | called by muse, mutect2, varscan2
- ZNF862 | c.651C>T p.F217= | Silent (SNP) | VAF 11/139 reads (8%) | called by muse, mutect2
- AC018521.7 | n.236C>T | RNA (SNP) | VAF 53/585 reads (9%) | catalogued as rs775554431; called by muse, mutect2
- ACOT11 | c.1629+959C>G | Intron (SNP) | VAF 12/336 reads (4%) | called by muse, mutect2
- ADAMTS13 | c.825-51C>T | Intron (SNP) | VAF 7/126 reads (6%) | catalogued as rs753339966; called by muse, mutect2
- ADCY10P1 | n.3617G>C | RNA (SNP) | VAF 12/278 reads (4%) | called by muse, mutect2
- ADGRV1 | c.*112G>A | 3'UTR (SNP) | VAF 10/192 reads (5%) | called by muse, mutect2
- AICDA | c.427+25C>T | Intron (SNP) | VAF 14/309 reads (5%) | called by muse, mutect2
- AL353804.7 | chrX:73849626 C>G | 5'Flank (SNP) | VAF 34/568 reads (6%) | called by muse, mutect2
- AMER1 | c.*3781G>C | 3'UTR (SNP) | VAF 11/110 reads (10%) | called by muse, varscan2
- AP000769.3 | chr11:65502967 C>A | 5'Flank (SNP) | VAF 20/212 reads (9%) | called by muse, mutect2
- AP5M1 | c.720+97C>T | Intron (SNP) | VAF 8/59 reads (14%) | catalogued as rs1338701990; called by muse, mutect2
- ATRNL1 | c.293+2613G>T | Intron (SNP) | VAF 26/187 reads (14%) | called by muse, mutect2, varscan2
- BLOC1S5-TXNDC5 | c.372+38456G>C | Intron (SNP) | VAF 18/240 reads (8%) | called by muse, mutect2
- C8orf34-AS1 | n.503G>A | RNA (SNP) | VAF 26/278 reads (9%) | called by muse, mutect2
- CAMTA2 | c.*38C>T | 3'UTR (SNP) | VAF 16/129 reads (12%) | called by muse, mutect2, varscan2
- CICP28 | chr7:56811931 G>T | 3'Flank (SNP) | VAF 44/353 reads (12%) | called by muse, varscan2
- COL6A1 | c.738+18C>A | Intron (SNP) | VAF 22/219 reads (10%) | catalogued as rs766602951; called by mutect2, varscan2
- CSMD2 | c.8312-7394C>A | Intron (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- CYYR1 | c.-216G>T | 5'UTR (SNP) | VAF 14/122 reads (11%) | catalogued as COSV100176809; called by muse, mutect2, varscan2
- DLG1 | c.483+10768C>T | Intron (SNP) | VAF 14/362 reads (4%) | called by muse, mutect2
- EPB41L1 | c.1669-3379G>C | Intron (SNP) | VAF 44/303 reads (15%) | catalogued as rs1000275100; called by muse, mutect2, varscan2
- F11R | c.*8C>T | 3'UTR (SNP) | VAF 34/186 reads (18%) | catalogued as rs201421335; called by muse, mutect2, varscan2
- FAM183BP | n.793G>C | RNA (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- FAM234B | c.*25G>C | 3'UTR (SNP) | VAF 33/196 reads (17%) | called by muse, mutect2, varscan2
- FRMD7 | c.285-40C>T | Intron (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
- FXYD7 | c.61+222C>T | Intron (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- GFRA1 | c.-13C>A | 5'UTR (SNP) | VAF 38/258 reads (15%) | called by muse, mutect2, varscan2
- GLA | c.639+42G>C | Intron (SNP) | VAF 14/246 reads (6%) | called by muse, mutect2
- HDAC6 | chrX:48801892 G>A | 5'Flank (SNP) | VAF 15/244 reads (6%) | called by muse, mutect2
- IGFBP3 | c.-70C>T | 5'UTR (SNP) | VAF 22/346 reads (6%) | catalogued as rs1268245661; called by muse, mutect2
- KLK7 | chr19:50983905 C>A | 5'Flank (SNP) | VAF 20/212 reads (9%) | called by muse, mutect2
- KRT6C | c.913-32T>A | Intron (SNP) | VAF 20/461 reads (4%) | catalogued as COSV52880150; called by muse, mutect2
- KRT6C | c.913-33G>T | Intron (SNP) | VAF 21/459 reads (5%) | called by muse, mutect2
- LRRC49 | c.194-423C>T | Intron (SNP) | VAF 12/276 reads (4%) | called by muse, mutect2
- LSM14B | c.427+1309G>C | Intron (SNP) | VAF 22/434 reads (5%) | catalogued as COSV53380218; called by muse, mutect2
- MALL | c.106-5765C>T | Intron (SNP) | VAF 25/244 reads (10%) | called by muse, mutect2
- MAP2K1 | c.568+8823G>T | Intron (SNP) | VAF 11/191 reads (6%) | called by muse, mutect2
- MAP2K3 | c.50-2249C>A | Intron (SNP) | VAF 38/592 reads (6%) | catalogued as rs1289138292; called by muse, mutect2
- MAP4K1 | c.314-20G>T | Intron (SNP) | VAF 39/178 reads (22%) | called by muse, mutect2, varscan2
- MARCHF1 | c.242+559A>G | Intron (SNP) | VAF 15/140 reads (11%) | catalogued as rs1247613116; called by muse, mutect2, varscan2
- MMGT1 | c.-277C>T | 5'UTR (SNP) | VAF 12/338 reads (4%) | called by muse, mutect2
- MPV17 | c.376-11T>A | Intron (SNP) | VAF 30/346 reads (9%) | called by muse, mutect2
- MRPL20 | chr1:1400221 C>G | 3'Flank (SNP) | VAF 20/320 reads (6%) | called by muse, mutect2
- MYCBP2 | c.8026+2910C>T | Intron (SNP) | VAF 12/261 reads (5%) | called by muse, mutect2
- NBPF11 | c.-548-2759G>T | Intron (SNP) | VAF 16/178 reads (9%) | called by muse, mutect2
- NDUFA8 | c.*16C>T | 3'UTR (SNP) | VAF 15/276 reads (5%) | called by muse, mutect2
- NEB | c.8890-2991C>T | Intron (SNP) | VAF 46/393 reads (12%) | catalogued as COSV51436371; called by muse, mutect2, varscan2
- NXF5 | n.788G>A | RNA (SNP) | VAF 19/328 reads (6%) | catalogued as rs1191714396, COSV53790325; called by muse, mutect2
- OR2M1P | n.479C>A | RNA (SNP) | VAF 12/313 reads (4%) | called by muse, mutect2
- OR7E5P | n.370A>T | RNA (SNP) | VAF 18/282 reads (6%) | called by muse, mutect2
- PDE7B | c.711+174G>C | Intron (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- PUDP | c.511-7298G>T | Intron (SNP) | VAF 24/284 reads (8%) | called by muse, mutect2
- RAB3GAP2 | c.*43G>A | 3'UTR (SNP) | VAF 10/94 reads (11%) | catalogued as rs777390114; called by muse, mutect2
- RASSF6 | c.63-4079C>G | Intron (SNP) | VAF 13/301 reads (4%) | catalogued as COSV56718526; called by muse, mutect2
- RFPL4AP1 | n.531C>T | RNA (SNP) | VAF 127/721 reads (18%) | catalogued as rs1419727158; called by muse, mutect2, varscan2
- RICTOR | c.4913+231G>C | Intron (SNP) | VAF 31/172 reads (18%) | called by muse, mutect2, varscan2
- RNF170 | c.*990G>C | 3'UTR (SNP) | VAF 23/378 reads (6%) | called by muse, mutect2
- RPL23 | c.13+199G>A | Intron (SNP) | VAF 16/358 reads (4%) | called by muse, mutect2
- SCN4B | c.*2303C>G | 3'UTR (SNP) | VAF 22/292 reads (8%) | called by muse, mutect2
- SCRN1 | c.342-3043G>T | Intron (SNP) | VAF 10/125 reads (8%) | catalogued as rs927524359; called by muse, mutect2
- SETDB2 | chr13:49444021 C>A | 5'Flank (SNP) | VAF 17/116 reads (15%) | catalogued as rs1345085143; called by muse, mutect2, varscan2
- SNORD116-2 | n.12G>A | RNA (SNP) | VAF 27/239 reads (11%) | called by muse, mutect2, varscan2
- SNX29P1 | n.654C>G | RNA (SNP) | VAF 41/520 reads (8%) | called by muse, mutect2
- SNX30 | c.1254+2118G>A | Intron (SNP) | VAF 14/259 reads (5%) | called by muse, mutect2
- SPATS2 | c.25+1381C>G | Intron (SNP) | VAF 30/372 reads (8%) | called by muse, mutect2
- SSPOP | n.15247G>T | RNA (SNP) | VAF 17/172 reads (10%) | catalogued as rs746707022, COSV65134923; called by muse, mutect2, varscan2
- SYCE1 | c.271+13G>T | Intron (SNP) | VAF 24/206 reads (12%) | called by muse, mutect2, varscan2
- TCF4 | c.990+21G>C | Intron (SNP) | VAF 24/320 reads (8%) | catalogued as rs1418901236, COSV61904332; called by muse, mutect2
- TMEM135 | c.*1484G>C | 3'UTR (SNP) | VAF 22/420 reads (5%) | called by muse, mutect2
- TMIGD2 | c.*7C>A | 3'UTR (SNP) | VAF 23/157 reads (15%) | called by muse, mutect2, varscan2
- TOR1AIP1 | c.475+646C>T | Intron (SNP) | VAF 18/248 reads (7%) | called by muse, mutect2
- TP53TG3D | c.*198C>A | 3'UTR (SNP) | VAF 47/460 reads (10%) | called by muse, mutect2, varscan2
- TSHR | c.692+272C>A | Intron (SNP) | VAF 23/317 reads (7%) | called by muse, mutect2
- TUBB3 | c.277+135C>G | Intron (SNP) | VAF 12/338 reads (4%) | called by muse, mutect2
- XIAP | c.*1645G>T | 3'UTR (SNP) | VAF 11/171 reads (6%) | called by muse, mutect2
- ZNF286A | c.334+1610C>T | Intron (SNP) | VAF 14/152 reads (9%) | called by muse, mutect2
- ZNF99 | c.*764G>T | 3'UTR (SNP) | VAF 34/312 reads (11%) | catalogued as rs1446443890; called by muse, varscan2
